Gene-level copy-number profile of tumor specimen TCGA-OX-A56R-01A from TCGA case TCGA-OX-A56R, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 68.9 years (25,178 days).
Specimen TCGA-OX-A56R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1b3b1603-0fe2-40b1-97f9-9962cb394193.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OX-A56R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c100a2f3-748d-42bf-9008-aa8a0a1d83b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 14,555; copy number 2: 41,913; copy number 3: 3,234; copy number 5: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OX-A56R-01A-11D-A33S-01): tumor purity 0.93, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,101,787–6,393,767, 10 genes (within-gene range 0–1): CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7.
- chr1:175,944,831–176,207,286, 1 gene (within-gene range 0–1): COP1.
- chr1:176,017,277–176,018,760, 1 gene: AL590723.1.
- chr1:176,217,541–176,306,095, 5 genes: U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1.
- chr9:21,967,752–22,128,103, 6 genes (within-gene range 0–1): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 93 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:27,491,682–30,179,014, 45 genes, copy number 5: AC073150.1, HIBADH, AC007130.1, TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1, RNU6-979P, JAZF1-AS1, PPIAP80, CREB5, AC005105.1, TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1.
- chr7:53,926,676–56,000,181, 48 genes, copy number 5: LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17.

Autosomal genes at a single copy (total copy number 1): 12,174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
